Somatic mutation profile of tumor specimen TCGA-DX-A3M1-01A (aliquot TCGA-DX-A3M1-01A-11D-A228-09) from TCGA case TCGA-DX-A3M1, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 79.2 years (28,932 days).
Specimen TCGA-DX-A3M1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d94ac296-94a6-4ecb-9045-bb2d427745c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3M1-10A (Blood Derived Normal), aliquot TCGA-DX-A3M1-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b5906c7-054b-4a60-9df5-fc211179aa53

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 9, Nonsense Mutation 2, Intron 1, Frame Shift Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN5A | c.3995C>T p.P1332L (on ENST00000333535 / NM_198056.3; = p.P1331L on NM_000335.5) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199473225, CM043869, COSV100348746; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS15 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV54508167; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV54460692; called by muse, mutect2, varscan2
- APLP1 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs751820034, COSV55701988; called by muse, mutect2, varscan2
- AQR | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs369825498; called by muse, mutect2, varscan2
- CALN1 | c.220G>A p.E74K (on ENST00000329008 / NM_001017440.3; = p.E116K on NM_031468.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1210215066, COSV100204106, COSV100204679; called by muse, mutect2, varscan2
- CDX4 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100999156; called by muse, mutect2, varscan2
- CEACAM4 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs112325334, COSV55731097, COSV99701080; called by muse, mutect2, varscan2
- CFAP206 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51536496; called by muse, mutect2, varscan2
- COL7A1 | c.8375del p.G2792Afs*7 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | catalogued as CD072388; called by mutect2, pindel, varscan2
- DCC | c.1235G>T p.S412I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV59092602; called by muse, mutect2, varscan2
- DENND2A | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1255378443, COSV99327019; called by muse, mutect2
- HECA | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs776935770, COSV62769096, COSV62770349; called by muse, mutect2, varscan2
- HHIP | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs1322361377; called by muse, mutect2, varscan2
- IGSF3 | c.3290C>T p.T1097M (on ENST00000369486 / NM_001007237.3; = p.T1117M on NM_001542.4) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs765418273; called by muse, mutect2, varscan2
- MAP3K5 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100753031; called by muse, mutect2, varscan2
- MYH3 | c.4480G>C p.D1494H | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56861233; called by muse, mutect2, varscan2
- MYH3 | c.3890G>C p.S1297T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV99878977; called by muse, mutect2, varscan2
- PCDHB7 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV50753762; called by muse, mutect2, varscan2
- PEG3 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55633050; called by muse, mutect2, varscan2
- PPARA | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as rs762274909; called by muse, mutect2, varscan2
- SP4 | c.2135G>A p.C712Y | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1431536810, COSV99755080; called by muse, mutect2
- APBA3 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AQP3 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCNL1 | c.1179T>G p.S393R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FSIP1 | c.1293G>T p.K431N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD2 | c.1619G>C p.W540S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GRIK3 | c.2213T>C p.M738T | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IL17RC | c.1587C>A p.C529* (on ENST00000295981 / NM_153461.4; = p.C443* on NM_032732.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- KCNA5 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- LZTS1 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP4K4 | c.2944A>G p.I982V (on ENST00000347699 / NM_001242559.2; = p.I900V on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PDHX | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHLDB1 | c.2837C>G p.S946C | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- PRMT2 | c.1280_1281dup p.V428Kfs*10 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- RAB6A | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2
- RORB | c.200G>A p.R67K (on ENST00000396204 / NM_001365023.1; = p.R56K on NM_006914.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN1A | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHANK2 | c.4775G>T p.G1592V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- SHROOM2 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.056); called by muse, mutect2
- SLC25A3 | c.751C>T p.P251S (on ENST00000228318 / NM_005888.3; = p.P250S on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/282 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, varscan2
- SLC30A6 | c.352A>C p.I118L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRPV3 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF683 | c.538T>A p.S180T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZUP1 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DNAH2 | c.1092G>A p.L364= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV50014944; called by muse, mutect2, varscan2
- FKBP10 | c.684G>A p.K228= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs369189363; called by muse, mutect2, varscan2
- FZD2 | c.459G>A p.Q153= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- GHDC | c.1278C>T p.S426= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- KIF21A | c.1512A>G p.R504= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100735269, COSV62777787; called by muse, mutect2, varscan2
- MYH3 | c.5430G>A p.K1810= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs1196090288; called by muse, varscan2
- PCK1 | c.1452C>A p.P484= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100100980; called by muse, mutect2
- TCF7L1 | c.306C>T p.F102= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV56400831; called by muse, mutect2
- UTP23 | c.411C>T p.L137= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, varscan2
- KRT18P55 | n.1212A>T | RNA (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23342G>A | Intron (SNP) | VAF 32/45 reads (71%) | catalogued as rs184388078; called by muse, mutect2, varscan2
